Somatic mutation profile of tumor specimen TCGA-HT-8113-01A (aliquot TCGA-HT-8113-01A-11D-2395-08) from TCGA case TCGA-HT-8113, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 49.8 years (18,173 days).
Specimen TCGA-HT-8113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9973c1f-8c25-4e94-8e4b-ae33f461ecb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8113-10A (Blood Derived Normal), aliquot TCGA-HT-8113-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/744d67d7-d9f0-49b9-b7fc-a9a17210fca8

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- AURKAIP1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57940219; called by muse, mutect2
- EIF3A | c.2757A>C p.R919S | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV64963708; called by muse, mutect2
- GYG1 | c.1026G>C p.K342N | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV56051373; called by muse, mutect2
- KCNK6 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327864352, COSV54581353; called by muse, mutect2
- LATS2 | c.2186T>A p.V729D | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101231619, COSV66880185; called by muse, mutect2
- MRPS5 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55535560; called by muse, mutect2, varscan2
- NRXN1 | c.2883C>G p.Y961* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV58497889; called by muse, mutect2
- TLR6 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs556706627, COSV67935165; called by muse, mutect2, varscan2
- WNK3 | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63616155; called by mutect2, varscan2
- ZFPL1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs570349109, COSV51871387; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.902T>G p.F301C | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58674845; called by muse, mutect2, varscan2
- N4BP2 | c.788dup p.N263Kfs*11 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- VPS35L | c.131del p.K44Rfs*5 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- HERPUD2 | c.441A>G p.P147= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV60947660; called by muse, mutect2, varscan2
- JCAD | c.426C>T p.A142= | Silent (SNP) | VAF 38/287 reads (13%) | catalogued as COSV64761928; called by muse, mutect2, varscan2
- OTOGL | c.5766C>T p.G1922= (on ENST00000547103; = p.G1913= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/225 reads (12%) | catalogued as rs756639152, COSV54024729; called by muse, mutect2, varscan2
- SORL1 | c.588T>A p.T196= | Silent (SNP) | VAF 68/354 reads (19%) | catalogued as COSV52763664; called by muse, mutect2, varscan2
- SORL1 | c.3588T>C p.Y1196= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
